Somatic mutation profile of tumor specimen ALCH-B36Y-TTP1-A (aliquot ALCH-B36Y-TTP1-A-5-0-D-A780-36) from ALCHEMIST case ALCH-B36Y, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.6 years (23,599 days).
Specimen ALCH-B36Y-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88b8b0ec-6551-4281-9f35-b4a282034ed0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B36Y-NB1-A (Blood Derived Normal), aliquot ALCH-B36Y-NB1-A-1-0-D-A780-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b5383f3-a045-427e-82e1-50264d97f00c

The open-access MAF lists 57 somatic variants for this specimen: 32 protein-altering or splice-affecting, 16 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 16, Intron 6, Splice Region 2, Nonsense Mutation 2, RNA 1, Splice Site 1, 3'UTR 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 46/252 reads (18%) | hotspot (GDC flag); catalogued as rs764735889, COSV52685086, COSV53209009; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CA13 | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 45/382 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.347); catalogued as COSV100410277, COSV58798947; called by muse, mutect2, varscan2
- CCDC178 | c.2182G>C p.D728H (on ENST00000383096 / NM_001105528.3; = p.D690H on NM_198995.3) | Missense Mutation (SNP) | VAF 31/401 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as COSV100287048; called by muse, mutect2
- CDK5RAP2 | c.4805G>A p.R1602H | Missense Mutation (SNP) | VAF 82/702 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs754501128, COSV62574200; called by muse, mutect2, varscan2
- MYH7 | c.635G>A p.G212D | Missense Mutation (SNP) | VAF 71/484 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs876661175; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PARS2 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.747); catalogued as rs376396001; called by muse, mutect2, varscan2
- RPUSD2 | c.1204G>A p.G402S | Missense Mutation (SNP) | VAF 25/194 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745562690; called by muse, varscan2
- SALL1 | c.1045A>T p.T349S | Missense Mutation (SNP) | VAF 34/233 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0.014); catalogued as rs1567316115; called by muse, mutect2, varscan2
- SERPINE1 | c.989C>T p.T330M | Missense Mutation (SNP) | VAF 104/658 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs192692662; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMPD3 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 58/310 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as rs199695897; called by muse, mutect2, varscan2
- SP100 | c.1124G>T p.R375L | Missense Mutation (SNP) | VAF 77/381 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.3); catalogued as rs758471253, COSV51020714; called by muse, mutect2, varscan2
- SUSD2 | c.1482C>T p.N494= | Splice Region (SNP) | VAF 7/42 reads (17%) | catalogued as rs759816631, COSV64203385; called by muse, mutect2, varscan2
- TCERG1 | c.2764C>T p.R922C | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99694844; called by muse, mutect2
- TMEM52B | c.371C>T p.S124F (on ENST00000381923 / NM_001079815.1; = p.S104F on NM_153022.4) | Missense Mutation (SNP) | VAF 63/691 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as rs779240379; called by muse, mutect2
- BMP1 | c.73T>G p.L25V | Missense Mutation (SNP) | VAF 36/274 reads (13%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- CACNA1C | c.2185G>A p.V729I | Missense Mutation (SNP) | VAF 45/404 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CFAP61 | c.3145T>C p.Y1049H | Missense Mutation (SNP) | VAF 56/481 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- DGAT2 | c.650G>T p.S217I | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.305); called by mutect2, varscan2
- FGGY | c.1575A>G p.K525= | Splice Region (SNP) | VAF 25/187 reads (13%) | called by muse, mutect2, varscan2
- HERC1 | c.1318T>C p.S440P | Missense Mutation (SNP) | VAF 31/330 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- MCM2 | c.1532A>G p.H511R | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MDM1 | c.419T>C p.V140A | Missense Mutation (SNP) | VAF 36/283 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NUTM2D | c.1459G>T p.D487Y | Missense Mutation (SNP) | VAF 24/289 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OLFM3 | c.1163G>A p.G388D (on ENST00000338858 / NM_001288821.1; = p.G368D on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/452 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.303); called by muse, mutect2
- PDE1A | c.1420C>T p.R474* | Nonsense Mutation (SNP) | VAF 38/276 reads (14%) | called by muse, mutect2, varscan2
- PPFIA4 | c.1132C>T p.L378F | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRMT6 | c.169C>A p.H57N | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRX | c.3642del p.T1215Pfs*2 | Frame Shift Del (DEL) | VAF 37/256 reads (14%) | called by mutect2, pindel, varscan2
- PSMA7 | c.254A>T p.N85I | Missense Mutation (SNP) | VAF 36/228 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- SPTA1 | c.4210T>A p.C1404S | Missense Mutation (SNP) | VAF 42/532 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- SRRM3 | c.1370+1G>C p.X457_splice | Splice Site (SNP) | VAF 10/72 reads (14%) | called by muse, mutect2, varscan2
- TLE1 | c.1850A>T p.D617V | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- B3GALNT2 | c.696C>T p.G232= | Silent (SNP) | VAF 68/801 reads (8%) | called by muse, mutect2
- B4GALT2 | c.102C>T p.V34= | Silent (SNP) | VAF 41/374 reads (11%) | catalogued as rs780266757; called by muse, mutect2, varscan2
- EEF1A2 | c.756C>T p.D252= | Silent (SNP) | VAF 36/197 reads (18%) | catalogued as rs866116461; called by muse, mutect2, varscan2
- GJD4 | c.97C>A p.R33= | Silent (SNP) | VAF 18/145 reads (12%) | catalogued as rs755718143; called by muse, mutect2
- HERC2 | c.3975G>A p.P1325= | Silent (SNP) | VAF 75/637 reads (12%) | catalogued as rs759567478, COSV55319796, COSV55328782; called by muse, mutect2, varscan2
- HMCN1 | c.10848G>T p.V3616= | Silent (SNP) | VAF 38/508 reads (7%) | called by muse, mutect2
- MEIS3 | c.753A>T p.G251= | Silent (SNP) | VAF 44/434 reads (10%) | called by muse, mutect2, varscan2
- MYBPC2 | c.945C>A p.I315= | Silent (SNP) | VAF 41/427 reads (10%) | called by muse, mutect2
- MYO18A | c.249C>T p.S83= | Silent (SNP) | VAF 29/198 reads (15%) | catalogued as rs1007434441; called by muse, mutect2, varscan2
- NLRP7 | c.1329C>T p.S443= | Silent (SNP) | VAF 15/131 reads (11%) | catalogued as COSV60178373; called by muse, mutect2, varscan2
- NOS1AP | c.1206G>A p.P402= | Silent (SNP) | VAF 24/200 reads (12%) | catalogued as rs1413407021; called by muse, mutect2, varscan2
- NXPE4 | c.351G>A p.L117= | Silent (SNP) | VAF 56/448 reads (13%) | called by muse, mutect2, varscan2
- RIMS2 | c.3771A>T p.T1257= | Silent (SNP) | VAF 41/397 reads (10%) | called by muse, mutect2, varscan2
- VPS13D | c.7950C>T p.F2650= | Silent (SNP) | VAF 82/740 reads (11%) | called by muse, mutect2, varscan2
- WBP1L | c.393G>A p.Q131= | Silent (SNP) | VAF 28/238 reads (12%) | called by muse, mutect2, varscan2
- ZNF536 | c.318C>T p.L106= | Silent (SNP) | VAF 60/475 reads (13%) | catalogued as rs778509421; called by muse, mutect2, varscan2
- AC132217.2 | c.*46+1284G>T | Intron (SNP) | VAF 66/318 reads (21%) | catalogued as rs771316451; called by muse, mutect2, varscan2
- COLQ | c.107-9011G>A | Intron (SNP) | VAF 82/443 reads (19%) | catalogued as rs772773496, COSV101082152; called by muse, varscan2
- DCHS2 | n.4126T>C | RNA (SNP) | VAF 21/186 reads (11%) | catalogued as rs376567618; called by muse, mutect2, varscan2
- GPI | c.866-21G>A | Intron (SNP) | VAF 37/293 reads (13%) | called by muse, mutect2, varscan2
- LMX1B | c.*13C>T | 3'UTR (SNP) | VAF 24/190 reads (13%) | catalogued as rs375458623, COSV100827144; called by muse, mutect2, varscan2
- RPL18 | c.198+14C>A | Intron (SNP) | VAF 63/516 reads (12%) | catalogued as rs1347385403; called by muse, mutect2, varscan2
- SERPINB10 | c.-19A>G | 5'UTR (SNP) | VAF 8/80 reads (10%) | called by muse, varscan2
- SNRNP200 | c.4164+187C>G | Intron (SNP) | VAF 9/79 reads (11%) | called by muse, mutect2, varscan2
- UBALD2 | c.121-47T>G | Intron (SNP) | VAF 51/380 reads (13%) | called by muse, mutect2, varscan2
